Somatic mutation profile of tumor specimen C3N-03190-01 (aliquot CPT0236560007) from CPTAC case C3N-03190, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 31.9 years (11,659 days).
Specimen C3N-03190-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e47a6ee-62e9-482b-a272-56169f958c91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03190-31 (Blood Derived Normal), aliquot CPT0236610002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aab3596a-a37a-48e1-b3c4-10f0141f0f24

The open-access MAF lists 44 somatic variants for this specimen: 26 protein-altering or splice-affecting, 14 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 14, Nonsense Mutation 2, 3'UTR 2, Intron 2, Splice Site 1, In Frame Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL2A1 | c.1597C>T p.R533* | Nonsense Mutation (SNP) | VAF 151/972 reads (16%) | catalogued as rs1085307608, CM034221; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 228/962 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 66/385 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CRAMP1 | c.2182C>T p.R728C | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs868557344; called by muse, mutect2, varscan2
- CYTH4 | c.76C>T p.R26* | Nonsense Mutation (SNP) | VAF 45/426 reads (11%) | catalogued as rs773973888, COSV50633680, COSV50635001; called by muse, mutect2, varscan2
- ELN | c.1432G>T p.G478C | Missense Mutation (SNP) | VAF 264/1740 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52706931; called by muse, mutect2, varscan2
- FAM210B | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 66/480 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); catalogued as rs531290851; called by muse, mutect2, varscan2
- KRT2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 60/456 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs747178935, COSV59011400; called by muse, mutect2, varscan2
- MMP2 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 151/1261 reads (12%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.985); catalogued as rs1019194457, COSV54605586; called by muse, mutect2, varscan2
- PAQR9 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 126/902 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.166); catalogued as COSV61417597; called by muse, mutect2, varscan2
- SELP | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 61/367 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs767813249, COSV55253485; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2582A>C p.Q861P | Missense Mutation (SNP) | VAF 26/464 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as rs139159145; called by muse, mutect2
- ZNF648 | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 94/1110 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs1161087875, COSV60572730; called by muse, mutect2
- B3GLCT | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 119/876 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- CAND1 | c.3363G>A p.M1121I | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.552); called by muse, mutect2
- CDK16 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 34/764 reads (4%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2
- CPNE8 | c.307A>G p.K103E | Missense Mutation (SNP) | VAF 39/301 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- FSIP2 | c.14765C>G p.A4922G | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); called by muse, mutect2
- FZR1 | c.1118C>T p.S373L | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); called by muse, mutect2
- HPX | c.155_157dup p.D52dup | In Frame Ins (INS) | VAF 37/297 reads (12%) | called by mutect2, pindel, varscan2
- LAMA4 | c.1225C>T p.H409Y (on ENST00000230538 / NM_001105206.3; = p.H402Y on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/868 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- RNF213 | c.12385G>T p.V4129F | Missense Mutation (SNP) | VAF 179/1191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- STRC | c.5119A>G p.S1707G | Missense Mutation (SNP) | VAF 82/1206 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2
- SUGCT | c.817-1G>A p.X273_splice | Splice Site (SNP) | VAF 48/366 reads (13%) | called by muse, mutect2, varscan2
- TAPBP | c.374T>C p.M125T | Missense Mutation (SNP) | VAF 83/697 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZFP41 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 98/803 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ATN1 | c.570A>T p.T190= | Silent (SNP) | VAF 62/454 reads (14%) | called by muse, mutect2, varscan2
- CCDC105 | c.444C>T p.N148= | Silent (SNP) | VAF 45/321 reads (14%) | catalogued as rs537607141; called by muse, mutect2, varscan2
- CUX1 | c.48C>T p.T16= (on ENST00000292535 / NM_181552.4; = p.T27= on NM_001913.5) | Silent (SNP) | VAF 28/504 reads (6%) | catalogued as rs376836450; called by muse, mutect2
- ESYT2 | c.2469C>T p.P823= (on ENST00000613624; = p.P747= on NM_020728.3) | Silent (SNP) | VAF 82/599 reads (14%) | called by muse, mutect2, varscan2
- FBXL19 | c.1821C>T p.C607= | Silent (SNP) | VAF 173/868 reads (20%) | catalogued as rs749247594; called by muse, mutect2, varscan2
- GRM4 | c.357G>A p.S119= | Silent (SNP) | VAF 82/586 reads (14%) | catalogued as rs374197166; called by muse, mutect2, varscan2
- MYT1L | c.897C>T p.Y299= | Silent (SNP) | VAF 94/837 reads (11%) | catalogued as rs377285450; called by muse, mutect2, varscan2
- NECAB2 | c.216G>T p.A72= | Silent (SNP) | VAF 168/1043 reads (16%) | catalogued as COSV100534054; called by muse, mutect2, varscan2
- PEG3 | c.3225C>T p.S1075= | Silent (SNP) | VAF 14/218 reads (6%) | catalogued as rs146308462; called by muse, mutect2
- PHGDH | c.858C>T p.A286= | Silent (SNP) | VAF 190/1151 reads (17%) | called by muse, mutect2, varscan2
- RASGRF1 | c.819C>T p.A273= | Silent (SNP) | VAF 66/916 reads (7%) | catalogued as rs752778899, COSV69176752; called by muse, mutect2
- TGFBI | c.1446C>T p.H482= | Silent (SNP) | VAF 27/272 reads (10%) | catalogued as rs766764647, COSV100526616; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMEM19 | c.153G>A p.P51= | Silent (SNP) | VAF 123/810 reads (15%) | catalogued as rs146789654; called by muse, mutect2, varscan2
- UNC5A | c.696C>T p.S232= | Silent (SNP) | VAF 42/223 reads (19%) | catalogued as rs553124719, COSV56173144; called by muse, mutect2, varscan2
- CDH4 | c.170-24587C>T | Intron (SNP) | VAF 109/599 reads (18%) | called by muse, mutect2, varscan2
- LHB | c.*73G>A | 3'UTR (SNP) | VAF 148/936 reads (16%) | catalogued as rs1252568176; called by muse, mutect2, varscan2
- TGM2 | c.1616-102C>A | Intron (SNP) | VAF 11/192 reads (6%) | called by muse, mutect2
- ZNF99 | c.*64C>A | 3'UTR (SNP) | VAF 126/790 reads (16%) | catalogued as COSV68056020; called by muse, mutect2, varscan2
